Gene-level copy-number profile of tumor specimen TCGA-R6-A6DN-01B from TCGA case TCGA-R6-A6DN, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Middle third of esophagus; Tumor grade: G3; Age at diagnosis: 58.2 years (21,259 days).
Specimen TCGA-R6-A6DN-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.cba800e4-39ed-43b0-8961-1cec57e482f9.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-R6-A6DN-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7f9fcb0d-7fc4-469e-bea5-8e1736126ee0

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 16; copy number 1: 485; copy number 2: 11,499; copy number 3: 27,724; copy number 4: 12,356; copy number 5: 3,940; copy number 6: 3,144; copy number 7: 196; copy number 8: 86; copy number 9: 60; copy number 11: 69; copy number 12: 3; copy number 13: 97; copy number 14: 14; copy number 16: 33; copy number 17: 23; copy number 18: 24; copy number 27: 5; copy number 65: 41.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-R6-A6DN-01B-11D-A31T-01): tumor purity 0.73, ploidy 3.37, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 14 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:59,747,277–61,251,459, 1 gene (within-gene range 0–3): FHIT.
- chr3:60,616,822–60,856,605, 6 genes: AC104164.2, MIR548BB, PPIAP70, AC104164.1, PPIAP71, U3.
- chr4:90,682,996–91,112,790, 3 genes: AC093729.1, TMSB4XP8, AC004054.1.
- chr5:59,703,606–59,703,703, 1 gene: MIR582.
- chr16:78,525,189–78,553,296, 3 genes: AC046158.4, AC046158.2, AC046158.3.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 651 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:36,795,527–37,136,146, 2 genes, copy number 7 (within-gene range 4–7): GRIK3, AL031430.1.
- chr1:37,161,563–37,203,716, 2 genes, copy number 7: MIR4255, RNU6-636P.
- chr1:157,794,403–158,700,652, 34 genes, copy number 8: FCRL1, CD5L, MRPS21P2, AL139010.1, KIRREL1, KIRREL1-IT1, SMIM42, LINC01704, ELL2P1, CD1D, AL138899.2, AL138899.1, CD1A, HMGN1P5, CD1C, CD1B, CD1E, OR10T2, OR10K2, OR10T1P, EI24P2, OR10K1, OR10R2, AL365440.1, OR10R3P, OR10R1P, HSP90AA3P, OR6Y1, OR6P1, OR10X1, OR10Z1, SPTA1, OR6K1P, OR6K2.
- chr1:160,739,057–162,039,567, 73 genes, copy number 7 (broad region; genes not listed).
- chr6:116,244,187–123,072,925, 94 genes, copy number 7 (broad region; genes not listed).
- chr6:133,952,170–136,550,819, 55 genes, copy number 14–65 (within-gene range 6–65): TBPL1, AL035699.1, SLC2A12, AL449363.1, AL449363.2, HMGA1P7, RN7SL408P, SGK1, RPS29P32, RNA5SP218, Y_RNA, AL355881.1, KRT8P42, LINC01010, Z84486.1, CHCHD2P4, CT69, AL078590.2, FAM8A6P, AL078590.1, AL596188.1, AL121970.1, MEMO1P2, ALDH8A1, AL445190.1, HBS1L, MIR3662, AL353596.1, MYB, MYB-AS1, MIR548A2, AL023693.1, AHI1, AL049552.1, AL049552.2, Y_RNA, LINC00271, GAPDHP73, AL035604.1, HMGB1P17, AL133319.1, PDE7B, AL360178.1, AL360178.2, AL138828.1, COX5BP2, AL138828.2, MTFR2, BCLAF1, AL023284.1, AL023284.4, MAP7, AL023284.3, AL023284.2, NDUFS5P1.
- chr6:137,657,998–142,637,889, 64 genes, copy number 9–27 (within-gene range 2–27) (broad region; genes not listed).
- chr8:109,240,919–111,236,203, 24 genes, copy number 7–8: NUDCD1, AC021237.1, ENY2, PKHD1L1, MAPK6P5, EBAG9, SYBU, AC079061.1, AC023245.2, U2, AC023245.1, KCNV1, AC027451.1, RPSAP48, AC073023.1, AC090819.1, AC025366.1, AP005357.1, NDUFB9P3, LINC01608, MTCO1P47, LINC01609, AC009930.1, EEF1A1P37.
- chr9:137,306,896–138,203,325, 24 genes, copy number 9 (within-gene range 6–9): EXD3, NOXA1, ENTPD8, NSMF, MIR7114, PNPLA7, MRPL41, DPH7, ZMYND19, ARRDC1, AL590627.2, ARRDC1-AS1, EHMT1, Metazoa_SRP, SETP5, AL590627.1, MIR602, AL772363.1, CACNA1B, AL591424.1, IL9RP1, TUBBP5, AL591424.2, AL954642.1.
- chr11:24,455,911–26,663,289, 13 genes, copy number 7 (within-gene range 5–7): Y_RNA, LUZP2, AC115990.1, AC087373.1, RPL36AP40, AC100770.1, LINC02699, AC013799.1, AC024341.1, ANO3, AC021698.1, ANO3-AS1, AC079064.1.
- chr11:54,591,480–56,642,471, 116 genes, copy number 8–13 (broad region; genes not listed).
- chr11:69,294,151–70,436,584, 36 genes, copy number 13–18: MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN.
- chr11:70,477,277–70,706,068, 6 genes, copy number 18: AP001271.1, AP001271.2, SHANK2-AS1, SHANK2-AS2, Y_RNA, AP000590.1.
- chr11:74,397,549–74,485,742, 1 gene, copy number 11 (within-gene range 4–11): AP001372.1.
- chr11:74,454,841–75,525,941, 44 genes, copy number 11: KCNE3, AP001372.3, CYCSP27, AP001372.4, LIPT2, AP001372.2, POLD3, RANP3, RN7SKP297, CHRDL2, AP001324.3, MIR4696, AP001324.2, AP001324.1, RNF169, XRRA1, AP000560.1, RN7SL239P, AP001992.1, AP001992.2, SPCS2, RNU6-216P, NEU3, AP003175.1, OR2AT2P, NPM1P50, OR2AT4, AP001972.4, SLCO2B1, OR2AT1P, AP001972.3, ZDHHC20P3, TPBGL, ARRB1, AP001972.1, AP001972.5, AP001972.2, MIR326, RPS3, SNORD15A, SNORD15B, KLHL35, GDPD5, AP002815.1.
- chr11:80,957,317–81,556,425, 5 genes, copy number 7–12: AP003398.1, AP003398.2, AP003464.1, MTND4LP18, MTND6P25.
- chr11:81,842,435–81,842,669, 1 gene, copy number 12: AP002802.2.
- chr11:83,455,012–85,627,922, 1 gene, copy number 11 (within-gene range 5–11): DLG2.
- chr11:84,545,131–87,491,110, 56 genes, copy number 11–16: HNRNPA1P72, AP000852.1, AP001825.1, AP001825.2, AP001825.3, AP000857.2, AP000857.1, HNRNPCP6, AP002803.1, AP003035.1, RNU6-1292P, TMEM126B, TMEM126A, CREBZF, CCDC89, SYTL2, AP000974.1, CCDC83, AP003128.1, SLC25A1P1, PICALM, RNU6-560P, LINC02695, FNTAP1, Metazoa_SRP, EED, MIR6755, AP003084.1, SETP17, HIKESHI, RN7SL225P, CCDC81, AP001831.1, PTP4A1P6, AP001148.1, ME3, AP003059.1, AP003059.2, PRSS23, MOB4P2, OR7E13P, AP000654.1, OR7E2P, AP001528.1, AP001528.2, FZD4, FZD4-DT, HNRNPCP8, TMEM135, XIAPP2, AP002967.1, AP001102.1, AP000811.1, PSMA2P1, AP003497.1, AP003497.2.

Autosomal genes at a single copy (total copy number 1): 474. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
